HCMI case HCM-CSHL-0820-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c045ba6f-3078-4dbd-9163-5ccd75cc1259

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1948; Vital status: Alive.

Diagnoses (2)
1. Non-small cell carcinoma (the primary disease): ICD-O-3 morphology code: 8046/3; ICD-10 code: C34.0; Tissue or organ of origin: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 70.8 years (25,843 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IVB; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: M1c; AJCC pathologic stage: Stage IVB; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Brain, NOS.
   Treatment given: Treatment type: Radiation, 2D Conventional; Treatment intent type: Neoadjuvant; Days to treatment start: 63 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 620 days (1.7 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 643 days (1.8 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Pharmaceutical Therapy, NOS.
2. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; ICD-10 code: C79.31; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 70.8 years (25,843 days).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin; Treatment intent type: Maintenance Therapy; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Paclitaxel; Treatment intent type: Maintenance Therapy; Treatment outcome: Treatment Ongoing.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 0 days.
- Days to follow up: 874 days (2.4 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 734.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- CD274 (IHC): Positive.
- EGFR substitution: Positive; Amino-acid change: L858R.
- KRAS mutation, nos: Negative.
- MET: Negative.
- RET rearrangement: Negative.
- ROS1 rearrangement (FISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 66.7 kg; Height: 157.5 cm; BMI: 27.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-CSHL-0820-C34-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0820-C34-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
